Somatic mutation profile of tumor specimen TCGA-IB-7646-01A (aliquot TCGA-IB-7646-01A-11D-2154-08) from TCGA case TCGA-IB-7646, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.6 years (22,148 days).
Specimen TCGA-IB-7646-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfa159b5-d83e-4c42-9b57-74bc5a4fe579.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7646-10A (Blood Derived Normal), aliquot TCGA-IB-7646-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/276e4e03-9697-483f-8071-86547b38bf1e

The open-access MAF lists 66 somatic variants for this specimen: 54 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 11, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/119 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMEM200C | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 18/163 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67309264, COSV67309384; called by muse, mutect2
- TP53 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 64/238 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs876659675, COSV52685038, COSV52712740, COSV52714133; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS10 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as COSV99546321; called by muse, mutect2, varscan2
- ALAS2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 114/235 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM983851, CM983852, COSV58191256; called by muse, mutect2, varscan2
- ARHGEF10 | c.3191A>G p.K1064R (on ENST00000398564; = p.K1039R on NM_014629.4) | Missense Mutation (SNP) | VAF 197/752 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs573337230, COSV100033441; called by muse, mutect2, varscan2
- ARHGEF17 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 144/474 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV99734719; called by muse, mutect2, varscan2
- BEST3 | c.1890C>G p.I630M | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV100437486, COSV100437861; called by muse, mutect2, varscan2
- BVES | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371189369; called by muse, mutect2, varscan2
- CCDC171 | c.1103A>T p.N368I | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV99899652; called by muse, mutect2, varscan2
- CCKAR | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 50/520 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV99810033; called by muse, mutect2
- COL5A1 | c.4050dup p.G1351Rfs*14 | Frame Shift Ins (INS) | VAF 31/137 reads (23%) | catalogued as rs758337699; called by mutect2, varscan2
- CPE | c.1399T>C p.W467R | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68583047; called by muse, mutect2
- CPSF2 | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 41/365 reads (11%) | catalogued as COSV100102421; called by muse, mutect2, varscan2
- CTSF | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074046; called by muse, mutect2, varscan2
- DHX40 | c.427-1G>A p.X143_splice | Splice Site (SNP) | VAF 195/907 reads (21%) | catalogued as COSV99232650; called by muse, mutect2, varscan2
- DPP6 | c.1502A>G p.Y501C (on ENST00000377770 / NM_001364500.2; = p.Y439C on NM_001936.5) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122499; called by muse, mutect2, varscan2
- DRD2 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs200352240, COSV100669241; called by muse, mutect2, varscan2
- EFEMP2 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 75/628 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV100337142; called by muse, mutect2, varscan2
- FN1 | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 147/733 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV100115519; called by muse, mutect2, varscan2
- GABRA6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 144/631 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754862222, COSV50877427; called by muse, mutect2, varscan2
- GABRB1 | c.487A>T p.M163L | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV99779769; called by muse, mutect2
- GTF3C1 | c.836T>G p.L279R | Missense Mutation (SNP) | VAF 98/365 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100648864; called by muse, mutect2, varscan2
- IL20RA | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs1428523572, COSV100359750; called by muse, mutect2, varscan2
- ING1 | c.473A>G p.D158G | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs931251533, COSV100311870; called by muse, mutect2, varscan2
- INHBA | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as rs756546726, COSV54219588, COSV54225084; called by muse, mutect2, varscan2
- IRS4 | c.1822A>T p.K608* | Nonsense Mutation (SNP) | VAF 458/970 reads (47%) | catalogued as COSV100929392; called by muse, mutect2, varscan2
- LRFN5 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 80/335 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs772023044, COSV53257915; called by muse, mutect2, varscan2
- LTB4R | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 141/485 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.766); catalogued as COSV99350405; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 56/350 reads (16%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MRGPRF | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs1342393360, COSV100307748; called by muse, mutect2, varscan2
- MYH14 | c.5830C>T p.R1944W | Missense Mutation (SNP) | VAF 52/401 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369147236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 98/330 reads (30%) | catalogued as rs761471964; called by mutect2, varscan2
- MYRF | c.2954G>A p.R985H (on ENST00000278836 / NM_001127392.3; = p.R950H on NM_013279.4) | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1207803361, COSV99606298; called by muse, mutect2, varscan2
- OR1C1 | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 159/777 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1274565656, COSV101376165; called by muse, mutect2, varscan2
- P2RY6 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 69/514 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs778069030, COSV62936408; called by muse, mutect2, varscan2
- PAGE1 | c.19T>G p.L7V | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated, low confidence (0.59); PolyPhen possibly damaging (0.515); catalogued as COSV101093904; called by muse, mutect2, varscan2
- POLA1 | c.3506T>C p.V1169A | Missense Mutation (SNP) | VAF 88/173 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV100984879; called by muse, mutect2, varscan2
- POM121L12 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 94/403 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as rs373781225, COSV68692188; called by muse, mutect2, varscan2
- PRICKLE1 | c.1778A>G p.E593G | Missense Mutation (SNP) | VAF 183/934 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100453335; called by muse, mutect2, varscan2
- PXT1 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 81/475 reads (17%) | catalogued as rs183075818, COSV101493380; called by muse, mutect2, varscan2
- QRICH2 | c.3350G>C p.G1117A | Missense Mutation (SNP) | VAF 21/526 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV99428709; called by muse, mutect2
- RAPGEF2 | c.2000G>T p.R667I | Missense Mutation (SNP) | VAF 49/746 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100030428; called by muse, mutect2
- SAC3D1 | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100100732; called by muse, mutect2, varscan2
- SEC24C | c.3268C>T p.R1090W | Missense Mutation (SNP) | VAF 201/643 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs769309794, COSV59543476; called by muse, mutect2, varscan2
- SLC30A8 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as rs754766609, COSV101438150; called by muse, mutect2, varscan2
- SPACA7 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); catalogued as COSV99366306; called by muse, mutect2, varscan2
- TBC1D16 | c.785dup p.S263Vfs*85 | Frame Shift Ins (INS) | VAF 70/343 reads (20%) | catalogued as rs1408486714; called by mutect2, pindel, varscan2
- TMEM30A | c.1063A>G p.N355D | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs1476720007, COSV100034668; called by muse, mutect2, varscan2
- TRIM42 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs753830695, COSV99647851; called by muse, mutect2, varscan2
- TSHZ2 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs201799053, COSV100296255; called by muse, mutect2, varscan2
- UNC5D | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 121/550 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs374094705, COSV54790778; called by muse, mutect2, varscan2
- USH2A | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 194/895 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771000800, COSV100227797; called by muse, mutect2, varscan2
- VWA5A | c.1710dup p.D571Rfs*6 | Frame Shift Ins (INS) | VAF 90/422 reads (21%) | called by pindel, varscan2
- APPL1 | c.750A>C p.T250= | Silent (SNP) | VAF 165/658 reads (25%) | catalogued as COSV99897283; called by muse, mutect2, varscan2
- CYLD | c.1320G>A p.L440= | Silent (SNP) | VAF 85/584 reads (15%) | catalogued as COSV100282075; called by muse, mutect2, varscan2
- ESCO2 | c.202C>T p.L68= | Silent (SNP) | VAF 71/267 reads (27%) | catalogued as COSV100533061; called by muse, mutect2, varscan2
- GLI3 | c.858C>A p.A286= | Silent (SNP) | VAF 56/531 reads (11%) | catalogued as COSV101229673; called by muse, mutect2, varscan2
- GLRX3 | c.291C>T p.I97= | Silent (SNP) | VAF 104/315 reads (33%) | catalogued as rs748966258, COSV58694626; called by muse, mutect2, varscan2
- JCHAIN | c.408C>A p.V136= | Silent (SNP) | VAF 78/314 reads (25%) | catalogued as COSV99636234; called by muse, mutect2, varscan2
- KLHL28 | c.1593C>T p.V531= | Silent (SNP) | VAF 90/630 reads (14%) | catalogued as rs766757580, COSV100752924; called by muse, mutect2, varscan2
- KRT38 | c.438C>T p.T146= | Silent (SNP) | VAF 137/592 reads (23%) | catalogued as rs751714826, COSV99878025; called by muse, mutect2, varscan2
- MATN4 | c.417G>A p.P139= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs761046524, COSV100636834; called by muse, varscan2
- MYH6 | c.1341C>G p.T447= | Silent (SNP) | VAF 57/434 reads (13%) | catalogued as COSV100676175; called by muse, mutect2, varscan2
- NUAK1 | c.939C>T p.S313= | Silent (SNP) | VAF 73/342 reads (21%) | catalogued as rs143829749; called by muse, mutect2, varscan2
- CTBP2 | c.58+11761A>G | Intron (SNP) | VAF 81/284 reads (29%) | catalogued as rs768911599, COSV58346999; called by muse, mutect2, varscan2
